Gene-level copy-number profile of tumor specimen ALCH-B2TV-TTP1-A from ALCHEMIST case ALCH-B2TV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.4 years (27,905 days).
Specimen ALCH-B2TV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 24cff2ad-1e93-4810-90c2-aa811b047189.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2TV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/4e551968-7ec3-4c1e-b511-705d8b7f12fe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 5,465; copy number 2: 50,255; copy number 3: 3,129; copy number 4: 6; copy number 5: 5; copy number 6: 7; copy number 11: 2; copy number 12: 1; copy number 13: 1; copy number 24: 1.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,454,665–3,487,627, 2 genes: ARHGEF16, AL512413.1.
- chr2:130,151,392–130,182,750, 1 gene (within-gene range 0–2): SMPD4.
- chr2:159,444,117–159,444,913, 1 gene (within-gene range 0–2): AC008277.2.
- chr8:144,393,229–144,444,440, 10 genes (within-gene range 0–2): CPSF1, MIR939, MIR1234, MIR6849, AC233992.3, SLC39A4, VPS28, TONSL, MIR6893, TONSL-AS1.
- chr12:132,603,150–132,610,582, 1 gene: LRCOL1.
- chr16:67,148,104–67,190,185, 8 genes (within-gene range 0–2): B3GNT9, TRADD, FBXL8, AC074143.1, HSF4, NOL3, KIAA0895L, EXOC3L1.
- chr17:79,132,722–79,136,402, 1 gene (within-gene range 0–2): AC021534.1.
- chr17:81,395,457–81,481,570, 6 genes (within-gene range 0–1): BAHCC1, AC110285.6, MIR4740, MIR3186, AC110285.4, LINC01971.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,549,053–7,741,396, 11 genes, copy number 5–24: FAM90A6P, FAM90A7P, FAM90A21P, FAM90A22P, FAM90A23P, OR7E157P, OR7E154P, FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P.
- chr21:44,107,373–44,210,114, 2 genes, copy number 5–12 (within-gene range 1–13): PWP2, GATD3A.
- chr21:44,172,169–44,207,399, 3 genes, copy number 11–13: AP001056.2, AP001056.1, AP001057.1.

Autosomal genes at a single copy (total copy number 1): 2,615. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
